Somatic mutation profile of tumor specimen MMRF_2706_1_BM_CD138pos (aliquot MMRF_2706_1_BM_CD138pos_T1_KHS5U_L14438) from MMRF case MMRF_2706, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.3 years (23,482 days).
Specimen MMRF_2706_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37f21ce7-2b95-4f14-92ea-92fa8b117e5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2706_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2706_1_PB_WBC_C2_KHS5U_L14439; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ace5cc0-3d90-4216-b303-4daf0ffb15f0

The open-access MAF lists 92 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 30, Intron 10, Silent 9, Frame Shift Del 2, 3'Flank 2, Splice Region 1, In Frame Del 1, Splice Site 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AIP | c.90T>G p.D30E | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.343); catalogued as CM1313647; called by muse, mutect2, varscan2
- ARHGEF7 | c.2327A>G p.Y776C (on ENST00000375741 / NM_001113511.2; = p.Y755C on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/103 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs771526499; called by muse, mutect2, varscan2
- H3C10 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.336); catalogued as rs759951492; called by muse, mutect2, varscan2
- IGHV3-33 | c.338A>T p.Y113F | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.287); catalogued as rs752557018; called by muse, varscan2
- IGHV3-72 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 196/434 reads (45%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.035); catalogued as rs527826416; called by muse, varscan2
- MAX | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 93/98 reads (95%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV52418152; called by muse, mutect2, varscan2
- MYPN | c.821del p.K274Sfs*18 | Frame Shift Del (DEL) | VAF 33/107 reads (31%) | catalogued as COSV62736687; called by pindel, varscan2
- PAPPA2 | c.2390G>A p.R797H | Missense Mutation (SNP) | VAF 233/437 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768943457; called by muse, mutect2, varscan2
- TNC | c.4970C>T p.T1657I | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.742); catalogued as rs745672568; called by muse, mutect2, varscan2
- ADSS1 | c.26A>T p.D9V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BECN1 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNB4 | c.759G>A p.R253= | Splice Region (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
- COL12A1 | c.1912C>T p.L638F | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CREBBP | c.1634T>A p.L545* | Nonsense Mutation (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- DCLRE1A | c.2378+1G>A p.X793_splice | Splice Site (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
- DYNC2H1 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FGFR3 | c.776_787del p.L259_N262del | In Frame Del (DEL) | VAF 16/192 reads (8%) | called by mutect2, pindel
- IER2 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 83/149 reads (56%) | SIFT tolerated (0.45); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- IGHV3-72 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 86/188 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- IL1RAPL1 | c.232A>C p.K78Q | Missense Mutation (SNP) | VAF 170/340 reads (50%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- JUNB | c.440A>G p.H147R | Missense Mutation (SNP) | VAF 191/410 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNT2 | c.485T>A p.L162Q | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- LRTM1 | c.374G>T p.R125M | Missense Mutation (SNP) | VAF 66/120 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, varscan2
- MAP7D2 | c.697T>G p.S233A | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- MECOM | c.1075A>G p.K359E (on ENST00000468789 / NM_001105078.4; = p.K547E on NM_004991.4) | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.757); called by muse, mutect2
- MRPS28 | c.467C>G p.A156G | Missense Mutation (SNP) | VAF 13/487 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2
- OR4Q2 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 15/447 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- PEDS1-UBE2V1 | c.984_988del p.S329Afs*9 | Frame Shift Del (DEL) | VAF 94/265 reads (35%) | called by mutect2, pindel, varscan2
- PLB1 | c.2508G>C p.Q836H | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- RYR2 | c.5318A>C p.N1773T | Missense Mutation (SNP) | VAF 199/448 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR3 | c.12370G>C p.E4124Q (on ENST00000389232; = p.E4125Q on NM_001036.6) | Missense Mutation (SNP) | VAF 91/199 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- SHOC1 | c.4117A>G p.N1373D | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.058); called by muse, mutect2
- TENM1 | c.1593C>G p.D531E | Missense Mutation (SNP) | VAF 107/245 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- THPO | c.708G>A p.M236I (on ENST00000649095 / NM_001290003.1; = p.M96I on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- TMEM182 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 182/391 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TMEM217 | c.389T>G p.F130C | Missense Mutation (SNP) | VAF 19/403 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- TMEM241 | c.792G>C p.L264F | Missense Mutation (SNP) | VAF 43/242 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TTN | c.8826C>A p.N2942K (on ENST00000591111; = p.N2896K on NM_003319.4) | Missense Mutation (SNP) | VAF 68/150 reads (45%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WHRN | c.1910C>G p.P637R | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- ZC3H12C | c.1898G>A p.S633N | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ANKRD6 | c.1866G>A p.K622= (on ENST00000339746 / NM_001242809.2; = p.K617= on NM_014942.4) | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2, varscan2
- ARL13B | c.1155C>G p.T385= (on ENST00000394222 / NM_001174150.2; = p.T278= on NM_144996.4) | Silent (SNP) | VAF 54/124 reads (44%) | called by muse, mutect2, varscan2
- KNDC1 | c.5049C>T p.H1683= | Silent (SNP) | VAF 88/168 reads (52%) | catalogued as rs149909557; called by muse, mutect2, varscan2
- LHFPL1 | c.246G>A p.Q82= | Silent (SNP) | VAF 90/191 reads (47%) | called by muse, mutect2, varscan2
- MTMR8 | c.513T>G p.V171= | Silent (SNP) | VAF 136/278 reads (49%) | called by muse, mutect2, varscan2
- NMBR | c.510C>T p.V170= | Silent (SNP) | VAF 40/66 reads (61%) | called by muse, mutect2, varscan2
- PID1 | c.714C>T p.S238= (on ENST00000354069 / NM_001330156.1; = p.S236= on NM_017933.5) | Silent (SNP) | VAF 199/413 reads (48%) | catalogued as rs574687706, COSV62472629; called by muse, mutect2, varscan2
- RNF207 | c.1329C>T p.D443= | Silent (SNP) | VAF 13/174 reads (7%) | called by muse, mutect2
- UGT2B17 | c.426A>G p.Q142= | Silent (SNP) | VAF 128/286 reads (45%) | catalogued as rs201804267; called by muse, mutect2, varscan2
- AP001993.1 | chr11:127101059 A>C | 3'Flank (SNP) | VAF 38/92 reads (41%) | called by muse, mutect2
- ARRDC4 | c.*2404G>A | 3'UTR (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- ARSJ | c.*1178A>G | 3'UTR (SNP) | VAF 42/87 reads (48%) | catalogued as rs903465712; called by muse, mutect2, varscan2
- ASTN2 | c.*322G>A | 3'UTR (SNP) | VAF 93/224 reads (42%) | called by muse, mutect2
- BCAP29 | c.690+2261C>T | Intron (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- C1orf198 | c.*517C>T | 3'UTR (SNP) | VAF 87/180 reads (48%) | called by muse, mutect2, varscan2
- CCDC90B | c.*1028C>A | 3'UTR (SNP) | VAF 36/79 reads (46%) | called by muse, mutect2, varscan2
- CHRM3 | c.*5165A>G | 3'UTR (SNP) | VAF 76/175 reads (43%) | called by muse, mutect2, varscan2
- EPCAM | c.*143C>T | 3'UTR (SNP) | VAF 82/156 reads (53%) | called by muse, mutect2, varscan2
- FAM117B | c.*933T>C | 3'UTR (SNP) | VAF 50/97 reads (52%) | called by muse, mutect2, varscan2
- FIBIN | c.*356T>G | 3'UTR (SNP) | VAF 63/136 reads (46%) | called by muse, mutect2, varscan2
- FPGT | c.*1400T>C | 3'UTR (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- HMGB3 | c.*2613T>G | 3'UTR (SNP) | VAF 42/101 reads (42%) | called by muse, mutect2, varscan2
- ITSN1 | c.*6871G>T | 3'UTR (SNP) | VAF 23/192 reads (12%) | called by muse, mutect2, varscan2
- LCP2 | c.*802C>T | 3'UTR (SNP) | VAF 59/115 reads (51%) | called by muse, mutect2, varscan2
- LTB | c.162+149C>T | Intron (SNP) | VAF 31/58 reads (53%) | called by muse, mutect2, varscan2
- LTB | c.162+148T>A | Intron (SNP) | VAF 31/59 reads (53%) | called by muse, mutect2, varscan2
- MAX | c.*576G>A | 3'UTR (SNP) | VAF 60/61 reads (98%) | called by muse, mutect2, varscan2
- MAX | c.*455G>A | 3'UTR (SNP) | VAF 74/76 reads (97%) | called by muse, varscan2
- MAX | c.296-84G>A | Intron (SNP) | VAF 78/80 reads (98%) | called by muse, varscan2
- MAX | c.296-452G>T | Intron (SNP) | VAF 38/42 reads (90%) | called by muse, varscan2
- MON2 | chr12:62602566 C>T | 3'Flank (SNP) | VAF 84/191 reads (44%) | called by muse, mutect2, varscan2
- NHLH2 | c.-8-204C>T | Intron (SNP) | VAF 72/134 reads (54%) | called by muse, mutect2, varscan2
- NT5C1B | c.439-44G>A | Intron (SNP) | VAF 26/50 reads (52%) | catalogued as rs1409787655; called by muse, mutect2, varscan2
- OPCML | c.*4883C>T | 3'UTR (SNP) | VAF 58/121 reads (48%) | catalogued as rs917558639; called by muse, mutect2, varscan2
- PAQR5 | c.*206G>A | 3'UTR (SNP) | VAF 37/88 reads (42%) | catalogued as COSV61817784; called by muse, mutect2, varscan2
- PRKAG2 | c.684+12_684+23del | Intron (DEL) | VAF 44/154 reads (29%) | called by mutect2, pindel, varscan2
- PRRX1 | c.*1066C>T | 3'UTR (SNP) | VAF 73/162 reads (45%) | called by muse, mutect2, varscan2
- RIN2 | c.*1238T>C | 3'UTR (SNP) | VAF 24/25 reads (96%) | called by muse, mutect2, varscan2
- RPUSD3 | c.*152A>G | 3'UTR (SNP) | VAF 72/167 reads (43%) | catalogued as rs1308988544; called by muse, mutect2, varscan2
- SPRR2D | c.*75C>T | 3'UTR (SNP) | VAF 74/309 reads (24%) | catalogued as COSV100835994; called by muse, mutect2, varscan2
- STIMATE | c.427+2333T>C | Intron (SNP) | VAF 30/65 reads (46%) | catalogued as rs1278223563; called by muse, mutect2, varscan2
- SUZ12 | c.*1568C>G | 3'UTR (SNP) | VAF 34/56 reads (61%) | called by muse, varscan2
- SUZ12 | c.*1690C>T | 3'UTR (SNP) | VAF 26/48 reads (54%) | catalogued as rs1167252169; called by muse, varscan2
- SUZ12 | c.*1768C>G | 3'UTR (SNP) | VAF 32/69 reads (46%) | called by muse, varscan2
- SUZ12 | c.*1814C>G | 3'UTR (SNP) | VAF 32/57 reads (56%) | called by muse, varscan2
- THRB | c.*2168C>A | 3'UTR (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- TMSB4X | chrX:12975481 A>G | 5'Flank (SNP) | VAF 155/324 reads (48%) | catalogued as COSV66082153; called by muse, mutect2, varscan2
- TPH1 | c.*755C>A | 3'UTR (SNP) | VAF 10/127 reads (8%) | called by muse, mutect2
- TSPYL5 | c.*2357_*2360del | 3'UTR (DEL) | VAF 4/38 reads (11%) | catalogued as rs890739383; called by pindel, varscan2
- UBE3B | c.631-377A>G | Intron (SNP) | VAF 79/173 reads (46%) | catalogued as rs1162222914; called by muse, mutect2, varscan2
- WASF2 | c.*942C>G | 3'UTR (SNP) | VAF 110/220 reads (50%) | called by muse, mutect2, varscan2
- WIPF2 | c.*2377_*2411del | 3'UTR (DEL) | VAF 30/84 reads (36%) | called by mutect2, pindel
